Surgical pathology report (de-identified scan), TCGA case TCGA-KN-8430, project TCGA-KICH (Kidney Chromophobe), tissue source site Harvard, specimen TCGA-KN-8430-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGIC DIAGNOSIS:

SPECIMEN LABELED "LEFT KIDNEY":
RENAL CELL CARCINOMA, chromophobe type (4.5 cm), Fuhrman Grade II/IV.
Tumor bulges but does not invade peri nephric adipose tissue.
Ureter, artery and vein margins are negative for tumor.
Soft tissue margin is negative for tumor.
Lymphovascular invasion is not identified.

ACCO Classification (6th Edition): pT1b NX MX.

The non-neoplastic kidney will be evaluated by Renal Pathology, and the findings will be reported in an addendum.

SPECIMEN LABELED "REGIONAL RETROPERITONEAL LYMPH NODE":
Fibrovascular and adipose tissue with no tumor present.
Lymphoid tissue is not identified.

CLINICAL DATA:

History: Left renal cell carcinoma.
Operation: Left radical nephrectomy, regional lymphadenectomy.
Clinical Diagnosis: Left renal carcinoma.

TISSUE SUBMITTED:

A/1. Left kidney
B/2. Regional retroperitoneal lymph node.

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patient's name and unit number.

Part A, "pt. left kidney", consists of a radical left nephrectomy specimen (13.5 g, 11.5 x 6.0 x 4.5 cm) with a kidney (13.0 x 6.0 x 4.5 cm), a ureter (1.5 cm in length x 0.7 cm in diameter), artery (0.8 cm in length x 0.3 cm in diameter), and vein (0.6 cm in length x 0.4 cm in diameter). Upon sectioning, there is a multinodular, cystic, tan/pink to tan/red mass (4.5 x 3.8 x 4.2 cm) with a fibrotic capsule showing 10% hemorrhage, and 30-40% necrosis. The mass is 2.5 cm from the artery, 2.7 cm from the vein, and 11.5 cm from the ureter margins. The cystic areas in the mass measure 0.3 to 1.9 cm in diameter. No lymph nodes are identified. No other lesions or masses are identified. The remainder of the kidney parenchyma is brown/tan and unremarkable. Gross photographs are taken. The outer surface of the specimen is inked black. Representative sections of tumor are submitted for cytogenetics, electron microscopy, quick fix and tissue banking. Representative sections of normal kidney are submitted for tissue bank, electron microscopy and immunofluorescence.

Micro A1: Ureter, artery and vein margins, en face, 3 frags.
Micro A2: Quick fix tumor, T1, 1 frag.
Micro A3: Tumor at closest approach to Gerota's fascia, 1 frag.
Micro A4-A5: Tumor with respect to kidney parenchyma, 1 frag.
Micro A6: Kidney cortex, 1 frag, RSS.
Micro A7: Candidate lymph nodes, 1 frag.

Part B, "pt. Regional retroperitoneal lymph nodes", consists of two fragments

[page 2 of 2]
[REDACTED]

of fibroadipose tissue (2.2 x 1.3 x 0.3 cm in aggregate) without any definitive lymph nodes. The entire specimen is submitted for histologic examination.

Micro B1: Multi frags, [REDACTED]

[REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

[REDACTED]

ADDENDUM:

RENAL PATHOLOGY EVALUATION OF KIDNEY PARENCHYMA:

LEFT RADICAL NEPHRECTOMY:

- MILD TO MODERATE CHRONIC CHANGES OF THE KIDNEY PARENCHYMA, INCLUDING:
- FOCAL GLOBAL GLOMERULOSCLEROSIS (7%)
- TUBULAR ATROPHY AND INTERSTITIAL FIBROSIS (10% OF THE PARENCHYMA)
- ARTERIOLAR SCLEROSIS, MODERATE (SEE NOTE)

NOTE:

The kidney parenchyma sample examined shows mild to moderate chronic changes as summarized above.

The kidney parenchyma has been reviewed by [REDACTED]

MICROSCOPIC DESCRIPTION:

Sections of formalin-fixed, paraffin embedded tissue (block A6) were evaluated using H&E, PAS, Jones' silver methenamine, and AFOG (trichrome) stains by light microscopy.

The sample consists of cortex and medulla. There are 220 glomeruli present, of which 12 (5.5%) are globally sclerosed. The remaining glomeruli show focal expansion of the mesangial areas. There are no discernible double contours of the glomerular capillary wall basement membranes. Several of the distal tubules contain PAS-positive hyaline casts. Approximately 10% of the cortical parenchyma shows tubular atrophy and interstitial fibrosis. Arteries and arterioles exhibit a moderate degree of sclerosis.

[REDACTED]

Source: NCI Genomic Data Commons file 6760d5e1-4a1e-463f-8da2-af8db638b719 (TCGA-KN-8430.48D9A36D-D5EB-4CC1-AA5C-BD4476DB8CDE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).